Somatic mutation profile of tumor specimen TCGA-HT-7471-01A (aliquot TCGA-HT-7471-01A-11D-2253-08) from TCGA case TCGA-HT-7471, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Brain, NOS; Tumor grade: G3; Age at diagnosis: 37.1 years (13,564 days).
Specimen TCGA-HT-7471-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e7409168-174c-4d5f-bbf2-0e7778dc7e74.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-7471-10B (Blood Derived Normal), aliquot TCGA-HT-7471-10B-01D-2253-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/929f7be1-85d0-4999-b92d-35b89429fe6e

The open-access MAF lists 18 somatic variants for this specimen: 13 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 9, Silent 5, Nonsense Mutation 2, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 51/119 reads (43%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- CCNT1 | c.1432G>T p.E478* | Nonsense Mutation (SNP) | VAF 38/118 reads (32%) | catalogued as COSV56066429; called by muse, varscan2
- CHST15 | c.1323C>G p.N441K | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.13); catalogued as COSV60566362; called by muse, mutect2, varscan2
- FUBP1 | c.616G>T p.E206* | Nonsense Mutation (SNP) | VAF 120/156 reads (77%) | catalogued as COSV53932598, COSV53939776; called by muse, mutect2, varscan2
- GATA6 | c.428A>G p.Q143R | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.264); catalogued as COSV52528409; called by muse, mutect2, varscan2
- MXRA5 | c.5389G>A p.G1797R | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.37); PolyPhen benign (0.013); catalogued as COSV54253876; called by muse, mutect2, varscan2
- MYO3A | c.4792G>A p.D1598N | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs746281374, COSV52170392; called by muse, mutect2, varscan2
- SON | c.2581A>G p.M861V | Missense Mutation (SNP) | VAF 94/221 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.867); catalogued as rs142324795; called by muse, varscan2
- TMEM248 | c.740A>G p.Y247C | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV58578653; called by muse, mutect2, varscan2
- TTYH3 | c.1463A>G p.N488S | Missense Mutation (SNP) | VAF 118/276 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV51863519; called by muse, mutect2, varscan2
- ZNF761 | c.1427G>A p.R476H | Missense Mutation (SNP) | VAF 36/39 reads (92%) | SIFT tolerated (0.13); PolyPhen benign (0.037); catalogued as rs748200943, COSV61889548; called by muse, mutect2, varscan2
- CIC | c.1491del p.V498* | Frame Shift Del (DEL) | VAF 63/107 reads (59%) | called by mutect2, pindel, varscan2
- RBM4 | c.529_536dup p.S180* | Frame Shift Ins (INS) | VAF 29/81 reads (36%) | called by mutect2, varscan2
- CHRNA3 | c.501G>A p.P167= | Silent (SNP) | VAF 32/198 reads (16%) | catalogued as rs577413653, COSV58775177; called by muse, mutect2, varscan2
- COLGALT1 | c.1272G>A p.V424= | Silent (SNP) | VAF 29/74 reads (39%) | catalogued as COSV53111887, COSV99395185; called by muse, mutect2, varscan2
- ELAPOR1 | c.288C>T p.N96= | Silent (SNP) | VAF 97/117 reads (83%) | catalogued as rs144842352; called by muse, mutect2, varscan2
- STAB1 | c.4860C>T p.H1620= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as rs1296992104, COSV58744061; called by muse, mutect2, varscan2
- TMC8 | c.768G>A p.V256= | Silent (SNP) | VAF 35/77 reads (45%) | catalogued as COSV59211798; called by muse, mutect2, varscan2
